CCDI case PBCHTA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/5d39f596-ac54-4ae1-9a15-80f44cbbed9f

Demographics
Sex at birth: female; Race: asian.

Diagnoses (1)
1. Neoplasm, malignant: ICD-O-3 morphology code: 8000/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.9 years (694 days).

Biospecimens (3 samples)
- Sample 0DSMWQ: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DSMY0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DSMYD: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
